Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3UU, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3UU-01A (Primary Tumor).

[page 1 of 3]
Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Clinical Diagnosis & History:

Bilateral thyroid nodularity with a diagnosis of papillary carcinoma of the right lobe.

Specimens Submitted:

- 1: Thyroid; total thyroidectomy
- 2: Lymph nodes, delphian; excision

DIAGNOSIS:

1. Thyroid; total thyroidectomy:

Tumor Type:

Papillary carcinoma, classical type

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Right lobe

Tumor Size:

Greatest diameter is 1.1 cm.

Tumor Encapsulation:

None Identified

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Invades the extrathyroidal fibroadipose tissue

Surgical Margins:

Tumor is present at inked anterior margin

Tumor Multicentricity:

Papillary microcarcinoma (0.7 cm) present in left lobe

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia

Exhibits chronic lymphocytic thyroiditis

Parathyroid Glands:

Not identified

ICD-O-3

carcinoma, papillary, thyroid

8240/3

Site: thyroid, NOS

C73.9

5-2-12
R0

[page 2 of 3]
2. Lymph nodes, delphian; excision:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 2

Number of lymph nodes with metastatic disease: 0

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh, labeled "total thyroidectomy, stitch marks right lobe" and consists of a thyroid weighing 16.5 g. A stitch is not grossly identified. The right lobe measures 3.5 x 1.5 x 1.1 cm, the left lobe measures 3.3 x 2.5 x 0.9 cm and the isthmus measures 2 x 0.9 x 0.4 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a 1.1 x 1.0 x 1.0 CM firm white nodule (N) in the right lobe, focally abutting the anterior and posterior thyroid capsule. Sections through the left lobe reveals two small nodules measuring respectively 0.3 and 0.4 cm in greatest dimension (N1 and N2). Sections through the isthmus reveals one nodule measuring 0.5 cm in greatest dimension (N3). The remaining thyroid parenchyma is red tan and beefy. Representative sections of the specimen submitted for The remaining tissue is serially sectioned and representatively submitted.

Summary of sections:

N - nodule, right lobe, entirely submitted

N1- nodule 1, left lobe, entirely submitted

N2 - nodule 2, left lobe, entirely submitted

RL - right lobe

LL - left lobe

IS - isthmus

N3- nodule, isthmus, entirely submitted

2. The specimen is received in formalin labeled, "Delphian nodes", and consists of two tan lymph nodes measuring 0.2 to 0.3 cm in greatest dimension. Entirely submitted.

Summary of sections:

LN - lymph nodes

Summary of Sections:

Part 1: Thyroid; total thyroidectomy

Block	Sect. Site	PCs
1	IS	1
1	LL	1
2	N	2
2	N1	2
1	N2	1
1	N3	1

[page 3 of 3]
1 RL 1

Part 2: Lymph nodes, delphian; excision

Block	Sect. Site	PCs
1	In	1

Source: NCI Genomic Data Commons file 96f71f37-a9ae-4f09-9852-98335270d8c4 (TCGA-DJ-A3UU.0345F565-DA23-40AC-8083-E74922DADF5F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).